Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAKQ, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAKQ-01A (Primary Tumor).

Concerning

Summary pathology report

Right orchidectomy; seminoma; diameter 5.5 cm; tumor confined to testis; no angio-invasion present; invasion of rete testis present, also pagetoid extension of ITGCNU in epithelium of rete.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

ICD O-3
Seminoma NOS 9061/3
Site (R) Testis NOS 9062.9
7/3/5/14

Source: NCI Genomic Data Commons file 7af32aea-5919-4a03-aa22-22945928e228 (TCGA-2G-AAKQ-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).